Somatic mutation profile of tumor specimen TCGA-G9-6333-01A (aliquot TCGA-G9-6333-01A-12D-1961-08) from TCGA case TCGA-G9-6333, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 66.4 years (24,249 days).
Specimen TCGA-G9-6333-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4cf92843-e033-4465-8789-45bfd3a40906.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6333-10A (Blood Derived Normal), aliquot TCGA-G9-6333-10A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8efa9b8d-c097-4ed7-8e0e-89ca70ece4e2

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 6, Frame Shift Ins 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.399C>A p.F133L | Missense Mutation (SNP) | VAF 29/155 reads (19%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen possibly damaging (0.718); catalogued as COSV61652814, COSV61652918; called by muse, mutect2, varscan2
- ACR | c.482G>A p.G161D | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53362010; called by muse, mutect2, varscan2
- ARFGEF1 | c.1967C>G p.P656R | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0.066); catalogued as COSV51616947, COSV51617305; called by muse, mutect2, varscan2
- CAMK4 | c.253dup p.I85Nfs*5 | Frame Shift Ins (INS) | VAF 12/54 reads (22%) | catalogued as rs925923300; called by mutect2, varscan2
- CCSER1 | c.298A>C p.M100L | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61468472; called by muse, mutect2
- CNTLN | c.887T>C p.V296A | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV52097297; called by muse, mutect2, varscan2
- CTNNA3 | c.2500C>T p.R834* | Nonsense Mutation (SNP) | VAF 28/143 reads (20%) | catalogued as rs202196166, COSV65522010, COSV65522795; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESYT2 | c.1996C>G p.H666D (on ENST00000613624; = p.H590D on NM_020728.3) | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.015); catalogued as COSV51756578; called by muse, mutect2, varscan2
- FAM135B | c.1166C>T p.P389L | Missense Mutation (SNP) | VAF 28/143 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52753309; called by muse, mutect2, varscan2
- FAM214A | c.1586A>C p.N529T | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55927229; called by muse, mutect2, varscan2
- HOXD4 | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1260434254, COSV60460685; called by muse, mutect2
- INPP5D | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV64040390; called by muse, mutect2, varscan2
- LMTK2 | c.3976G>T p.D1326Y | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs373561525, COSV52003881; called by muse, mutect2, varscan2
- LUC7L | c.771C>G p.S257R | Missense Mutation (SNP) | VAF 18/276 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV53460713; called by muse, mutect2
- MAGEL2 | c.2392C>T p.P798S | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV58569132; called by muse, mutect2
- MYH10 | c.3184G>A p.G1062R | Missense Mutation (SNP) | VAF 27/103 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.689); catalogued as COSV52611209; called by muse, mutect2, varscan2
- OR9G4 | c.424A>C p.T142P | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.522); catalogued as COSV57249845; called by muse, mutect2
- PAPSS2 | c.1807G>A p.V603I | Missense Mutation (SNP) | VAF 11/121 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.122); catalogued as COSV63265147; called by muse, mutect2
- PHACTR1 | c.1073G>A p.G358D | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.922); catalogued as COSV60681558; called by muse, mutect2
- PHTF1 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs764128375, COSV63367136; called by muse, mutect2, varscan2
- TRIO | c.2410T>G p.S804A | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.005); catalogued as COSV60095556; called by muse, mutect2
- ZNF594 | c.1895C>T p.S632F | Missense Mutation (SNP) | VAF 12/194 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); catalogued as COSV68386214; called by muse, mutect2
- AGK | c.1089G>A p.T363= | Silent (SNP) | VAF 7/104 reads (7%) | catalogued as rs747085485, COSV100814610, COSV62595964; called by muse, mutect2
- COL6A1 | c.2778C>T p.F926= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs1173361496, COSV62615603; called by muse, mutect2, varscan2
- KIF21B | c.1182G>A p.R394= | Silent (SNP) | VAF 20/97 reads (21%) | catalogued as COSV59760001; called by muse, mutect2, varscan2
- MME | c.1287A>G p.E429= | Silent (SNP) | VAF 22/121 reads (18%) | catalogued as COSV64710790; called by muse, mutect2, varscan2
- OBSCN | c.3570G>C p.V1190= | Silent (SNP) | VAF 13/91 reads (14%) | catalogued as COSV52828857; called by muse, mutect2, varscan2
- RXRG | c.1377G>A p.P459= | Silent (SNP) | VAF 25/135 reads (19%) | catalogued as rs149087358; called by muse, mutect2, varscan2
- C16orf89 | c.*225G>A | 3'UTR (SNP) | VAF 9/142 reads (6%) | catalogued as COSV60126554; called by muse, mutect2
